Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZR-06A (Metastatic).

[page 1 of 2]
MALIGNANT MELANOMA MINIMUM DATA SET

ADDRESS FOR REPORT: DERMATOLOGY

CLINICAL HISTORY:

: Bleeding mole right chest.

MACROSCOPIC:

Excision biopsy right chest. Skin ellipse measuring 4.5 x 1.8 x 1.9 cm. There is a central brown nodule with a maximum diameter of 1.9 cm and a depth of 1.7 cm. No orientation is given.

MICROSCOPIC:

Tumour type	Nodular
Growth phase	Vertical
Breslow thickness (mm)	7.30
Ulceration	Present
Ulceration diameter (mm)	5.0
Mitotic rate (/sq mm)	18
Regression	Absent
Lymphovascular invasion	Absent
Perineural invasion	Absent
Microsatellites	Absent
Coexistent naevus	Absent
Tumour infiltrating lymphocytes	Non-brisk
Completely Excised	Yes
Deep margin (mm)	3.5
Circumferential margin (mm)	3.0
Stage	pT4b

ICD-O-3
Melanoma, nodular 8721/3
Site Lymph node, axilla C774
05/19/14

DIAGNOSIS:

Skin of Right Chest: Nodular Malignant Melanoma.

REPORTED BY:

DATE AUTHORISED:

Sample

(Tissue) Collected

Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTICS

Report to Cancer Registry

HISTOPATHOLOGY REPORT

LAB No:

[page 2 of 2]
CASE HISTORY:

7.3 mm Breslow thickness malignant melanoma right flank/chest wall,
and palpable lymphadenopathy right axilla. Axillary dissection.
WLE 2 cm margin right flank.
Excision biopsy of pigmented lesion left thigh.

MACROSCOPIC:

1. Right axillary dissection tissue which consists of an overlying skin ellipse, subcutaneous fat, and muscle. The skin ellipse measures 8.5 x 1 x 0.2 cm. There is a well-circumscribed nodular mass within the subcutaneous tissue 4.5 x 3.2 x 1.5 cm. The surface of this nodule has been inked. There is an area of induration on the nodule which relates to surgical dissection. Block A-D = sample from the nodule. E-J = lymph nodes.
2. Wide local excision. Skin ellipse with subcutaneous fat 8.5 x 3.5 x 1 cm. Orientation suture designated 12 o'clock. This margin has been inked blue. There is a linear scar 5 cm in length with two focal areas of ulceration along the scar.
3. Excision lesion left thigh. Skin ellipse 2 x 0.8 x 0.2 cm. There is a variably hyperpigmented lesion 1 x 0.5 x 0.2 cm. All embedded.

MICROSCOPY:

1. Thirteen out of fourteen lymph nodes show metastatic malignant melanoma. No extracapsular invasion is seen. BRAF staining to follow.
2. Skin which shows scar tissue formation. No residual melanoma recognised.
3. Skin which shows an atypical compound melanocytic naevus. The junctional component shows architectural and variable (up to high grade) cytological atypia. The intradermal component is mature. Peripheral clearance: 1.3 mm.

DIAGNOSIS:

1. RIGHT AXILLARY DISSECTION: 13 OF 14 NODES POSITIVE FOR METASTATIC MALIGNANT MELANOMA.
2. WIDE LOCAL EXCISION (RIGHT FLANK): SCAR TISSUE.
3. EXCISION LESION (LEFT THIGH): COMPOUND ATYPICAL (DYSPLASTIC) MELANOCYTIC NAEVUS.

REPORTED BY:

Histopathology
Consultant Histopathologist

REPORT DATE:

Source: NCI Genomic Data Commons file 31839438-638c-4e4e-96fe-fb78965364fe (TCGA-WE-A8ZR.693528B1-CE0F-4008-8257-3E981A778AFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).